Somatic mutation profile of tumor specimen TCGA-DD-A4NE-01A (aliquot TCGA-DD-A4NE-01A-11D-A27I-10) from TCGA case TCGA-DD-A4NE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 75.4 years (27,549 days).
Specimen TCGA-DD-A4NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b90bc838-db66-4276-b10d-46881ced6c31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NE-11A (Solid Tissue Normal), aliquot TCGA-DD-A4NE-11A-11D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41ff1752-42f1-4e99-a05a-cce0982c722f

The open-access MAF lists 71 somatic variants for this specimen: 51 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 3, 3'UTR 2, In Frame Del 1, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3155C>A p.T1052K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV55882314, COSV55947907; called by muse, mutect2, varscan2
- AASDH | c.508A>C p.I170L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52710080; called by muse, mutect2, varscan2
- ACAA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs115896366; called by muse, mutect2, varscan2
- ACOT12 | c.1337A>G p.D446G | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs765632918, COSV56897693; called by muse, mutect2, varscan2
- ADNP | c.1521G>A p.M507I | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV62426726; called by muse, varscan2
- ATP8A2 | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54974519; called by muse, mutect2, varscan2
- CCDC184 | c.79G>C p.A27P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57252462; called by mutect2, varscan2
- CD4 | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.13); catalogued as COSV50595080, COSV50595370; called by muse, mutect2, varscan2
- CDKN1A | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 116/154 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55187956, COSV55191258; called by muse, mutect2
- CELF3 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51885513; called by muse, mutect2, varscan2
- CHD7 | c.4052G>A p.R1351K | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71114101; called by muse, mutect2, varscan2
- CNGA3 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 120/223 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM980375, COSV55627817; called by muse, mutect2, varscan2
- CTSG | c.94del p.R32Afs*29 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as COSV99361492; called by mutect2, pindel, varscan2
- CUBN | c.4375T>C p.S1459P | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV64725613; called by muse, mutect2, varscan2
- DDX5 | c.1625A>G p.N542S | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs200823006, COSV56751072; called by muse, mutect2, varscan2
- DNAH12 | c.1352T>A p.L451H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.172); catalogued as COSV61064613; called by muse, mutect2
- DNMT1 | c.522-1G>T p.X174_splice | Splice Site (SNP) | VAF 55/144 reads (38%) | catalogued as COSV100531480; called by muse, mutect2, varscan2
- FAM205A | c.252-1G>T p.X84_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV66490055; called by muse, mutect2, varscan2
- GEN1 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs748788774, COSV58058316; called by muse, mutect2, varscan2
- GORAB | c.393C>A p.C131* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as COSV63026813; called by muse, mutect2, varscan2
- GPR85 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV51783364; called by muse, mutect2, varscan2
- GRM6 | c.2542G>T p.E848* | Nonsense Mutation (SNP) | VAF 95/217 reads (44%) | catalogued as COSV51448920; called by muse, mutect2, varscan2
- GRM7 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV63166933; called by muse, varscan2
- HMGCS1 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778890257, COSV57291403; called by muse, mutect2, varscan2
- KIAA1549 | c.1760G>T p.S587I | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV54326514; called by muse, mutect2, varscan2
- LCORL | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs867841298, COSV58839753; called by muse, mutect2, varscan2
- LRP1B | c.2770G>C p.A924P | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV63341662, COSV63341982, COSV63341998; called by muse, mutect2, varscan2
- LRRC4C | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 90/307 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53435703, COSV99539818; called by mutect2, varscan2
- MYH4 | c.4213G>T p.E1405* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV55125074; called by muse, mutect2, varscan2
- MYOZ1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63772057; called by muse, mutect2
- NCF4 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV50627545, COSV99030549; called by muse, mutect2, varscan2
- OR4C6 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58605997; called by muse, mutect2, varscan2
- PLA2R1 | c.3519G>T p.W1173C | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784283, COSV51785705; called by muse, mutect2, varscan2
- PTEN | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 99/126 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as CM991083, COSV64291511, COSV64305247; called by muse, mutect2, varscan2
- RPL22 | c.75C>A p.C25* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | catalogued as COSV52379186; called by muse, mutect2, varscan2
- SENP2 | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV56197367; called by muse, mutect2, varscan2
- SEPHS2 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV72100822; called by muse, mutect2, varscan2
- SSH3 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs370197853; called by muse, mutect2, varscan2
- TNN | c.3427+1G>C p.X1143_splice | Splice Site (SNP) | VAF 37/174 reads (21%) | catalogued as COSV53434282; called by muse, mutect2, varscan2
- TSR3 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50105285; called by mutect2, varscan2
- UNC13A | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs750232302, COSV53191703, COSV99409238; called by muse, mutect2, varscan2
- VIT | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64898920; called by muse, mutect2, varscan2
- ZNF385D | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746789731, COSV55772119; called by muse, mutect2, varscan2
- CEP120 | c.1439_1440del p.Y480Sfs*12 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by pindel, varscan2
- DNMT1 | c.522C>T p.G174= | Splice Region (SNP) | VAF 56/145 reads (39%) | called by muse, mutect2, varscan2
- KIAA1671 | c.1825A>T p.T609S | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- KIF27 | c.2768A>C p.E923A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, varscan2
- KNTC1 | c.1861-4_1869del p.X621_splice | Splice Site (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- OBSCN | c.4465_4470del p.R1489_M1490del | In Frame Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- RB1 | c.485_486insA p.F162Lfs*9 | Frame Shift Ins (INS) | VAF 22/36 reads (61%) | called by mutect2, pindel, varscan2
- SPAG6 | c.1417_1426del p.Y473Vfs*10 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- AAR2 | c.219T>A p.P73= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV57924893; called by muse, mutect2, varscan2
- EPB41L4A | c.108G>C p.T36= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV54863080, COSV54879195; called by muse, mutect2, varscan2
- EZR | c.228C>A p.L76= | Silent (SNP) | VAF 71/185 reads (38%) | catalogued as COSV61455899; called by muse, mutect2, varscan2
- GLYAT | c.15G>A p.L5= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV53540473; called by muse, mutect2, varscan2
- ITGB3 | c.543A>G p.A181= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV71385184; called by muse, mutect2, varscan2
- MYH8 | c.3027C>T p.T1009= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV67971439; called by muse, mutect2, varscan2
- OR5M3 | c.204T>C p.D68= | Silent (SNP) | VAF 61/412 reads (15%) | catalogued as COSV56568295; called by muse, mutect2, varscan2
- PRDM13 | c.2028T>C p.P676= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV65030603; called by muse, mutect2
- RTEL1 | c.2682C>T p.D894= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs535831345, COSV58900768; called by muse, mutect2, varscan2
- SDK1 | c.1938C>T p.S646= | Silent (SNP) | VAF 113/240 reads (47%) | catalogued as COSV67386678; called by muse, mutect2, varscan2
- SHOX2 | c.432G>C p.R144= (on ENST00000441443 / NM_006884.3; = p.R168= on NM_003030.4) | Silent (SNP) | VAF 98/205 reads (48%) | catalogued as COSV67464665; called by muse, mutect2, varscan2
- SPAST | c.1080T>C p.L360= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV59517279; called by muse, mutect2, varscan2
- STEAP3 | c.774A>T p.T258= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV61530870; called by muse, mutect2, varscan2
- THAP3 | c.144C>T p.P48= | Silent (SNP) | VAF 77/171 reads (45%) | catalogued as COSV50011681; called by muse, mutect2, varscan2
- TLL2 | c.2151C>T p.D717= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs779196554, COSV63575349; called by muse, varscan2
- ZFHX4 | c.1830C>T p.G610= | Silent (SNP) | VAF 58/105 reads (55%) | catalogued as rs760924722, COSV51492507, COSV99263147; called by muse, mutect2, varscan2
- ZSWIM4 | c.1869C>T p.D623= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV54325782; called by muse, mutect2, varscan2
- PABPC5 | c.*886C>T | 3'UTR (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100442015; called by muse, mutect2, varscan2
- PNMA6A | c.*516G>T | 3'UTR (SNP) | VAF 42/97 reads (43%) | catalogued as COSV101357750; called by muse, mutect2, varscan2
- SH2D3C | c.556-3498G>C | Intron (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
